Gene-level copy-number profile of tumor specimen TCGA-CN-4729-01A from TCGA case TCGA-CN-4729, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 73.1 years (26,713 days).
Specimen TCGA-CN-4729-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.3058fba3-ac39-4c46-98ef-fb581a3fd71a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CN-4729-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/27a1dbef-c464-48ae-9a11-f05a13b995a7

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 820; copy number 2: 10,003; copy number 3: 18,878; copy number 4: 18,438; copy number 5: 4,448; copy number 6: 3,732; copy number 7: 685; copy number 8: 1,973; copy number 9: 546; copy number 10: 128; copy number 13: 111; copy number 14: 10; copy number 22: 13; copy number 24: 10; copy number 34: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CN-4729-01A-01D-1432-01): tumor purity 0.29, ploidy 3.78, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,482 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:232,160,091–248,919,946, 388 genes, copy number 7 (broad region; genes not listed).
- chr3:107,220,744–108,757,384, 23 genes, copy number 8: DUBR, AC063944.1, CSP2, AC063944.2, CCDC54, LINC01990, BBX, LINC00636, LINC00635, AC012020.1, CD47, LINC01215, IFT57, HHLA2, HNRNPA1P17, MYH15, AC069499.1, CIP2A, SNORA70, AC069499.2, DZIP3, AC092185.1, RETNLB.
- chr4:19,455,418–20,037,972, 4 genes, copy number 7: AC024230.1, AC110767.1, AC114728.1, AC098862.1.
- chr5:58,198–23,329,892, 380 genes, copy number 9–13 (broad region; genes not listed).
- chr7:28,279,211–29,742,594, 22 genes, copy number 7: PPIAP80, CREB5, AC005105.1, TRIL, AC005013.1, AC005162.2, AC005162.1, CPVL, CPVL-AS1, AC005232.1, AC004593.2, CHN2, AC004593.1, CHN2-AS1, NANOGP4, AC007255.1, GTF3C6P3, PRR15, ZNRF2P2, TMSB4XP3, DPY19L2P3, MIR550A3.
- chr8:35,235,475–35,796,550, 1 gene, copy number 7 (within-gene range 2–7): UNC5D.
- chr8:35,525,176–120,813,359, 1,275 genes, copy number 7–22 (broad region; genes not listed).
- chr11:100,687,288–109,823,893, 139 genes, copy number 9–14 (within-gene range 3–14) (broad region; genes not listed).
- chr11:125,625,665–129,860,003, 76 genes, copy number 9–34 (within-gene range 1–34) (broad region; genes not listed).
- chr12:164,664–5,946,232, 135 genes, copy number 10–14 (broad region; genes not listed).
- chr12:122,687,125–126,043,485, 104 genes, copy number 8 (broad region; genes not listed).
- chr13:46,052,497–114,337,626, 842 genes, copy number 8 (within-gene range 6–8) (broad region; genes not listed).
- chr18:47,390–500,722, 11 genes, copy number 8 (within-gene range 4–8): TUBB8B, AP001005.3, IL9RP4, AP001005.2, ROCK1P1, MIR8078, USP14, THOC1, AP000845.1, AP000915.1, COLEC12.
- chr18:2,847,006–4,455,307, 38 genes, copy number 9 (within-gene range 5–9): EMILIN2, LPIN2, AP000919.3, CHORDC1P4, AP000919.1, AP000919.2, SNRPCP4, AP005431.1, SNORA70, MYOM1, RNU7-25P, AP005329.2, AP005329.3, MYL12A, AP005329.1, MYL12B, AP001025.1, LINC01895, RPL31P59, IGLJCOR18, RPL21P127, TGIF1, BOD1P1, GAPLINC, DLGAP1, RN7SL39P, AP002472.1, DLGAP1-AS1, DLGAP1-AS2, AP002478.1, AP002478.2, DLGAP1-AS3, MIR6718, RNU6-831P, DLGAP1-AS4, GAPDHP66, DLGAP1-AS5, AP005208.1.
- chr18:71,028,770–71,944,577, 11 genes, copy number 22–24: AC090415.1, AC091691.3, AC091691.2, AC091691.1, LINC01541, AC090312.1, AC090312.2, LINC01899, AC027458.1, AC069114.1, AC069114.2.
- chr21:33,403,413–34,615,113, 33 genes, copy number 9: IFNGR2, TMEM50B, RPS5P3, AP000302.1, DNAJC28, GART, BTF3P6, SON, MIR6501, DONSON, AP000311.1, CRYZL1, ITSN1, ATP5PO, LINC00649, RN7SL740P, AP000569.1, MRPS6, SLC5A3, AP000317.2, RPS5P2, LINC00310, AP000317.1, AP000320.1, KCNE2, SMIM11A, FAM243A, AP000322.2, SMIM34A, AP000322.1, KCNE1, AP000324.1, RCAN1.

Autosomal genes at a single copy (total copy number 1): 820. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
